Gene-level copy-number profile of tumor specimen ALCH-AET9-TTP1-A from ALCHEMIST case ALCH-AET9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 58.9 years (21,524 days).
Specimen ALCH-AET9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66365bbc-79e8-46b0-9aea-7f971141fecb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AET9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/449aa921-dfe4-410d-92f4-a56c87fd219f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 163; copy number 1: 8,868; copy number 2: 48,573; copy number 3: 708; copy number 4: 72; copy number 5: 5; copy number 7: 16; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 163 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:911,435–1,074,306, 18 genes (within-gene range 0–4): AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr2:241,869,600–241,873,823, 1 gene: RTP5.
- chr5:139,647,299–139,844,466, 8 genes (within-gene range 0–2): CXXC5, CXXC5-AS1, AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2.
- chr7:5,431,335–5,563,902, 6 genes (within-gene range 0–1): FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1.
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr8:22,042,398–22,232,101, 12 genes: FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:93,184,916–93,320,572, 1 gene (within-gene range 0–2): WNK2.
- chr11:47,331,406–47,449,143, 7 genes: MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN.
- chr11:63,911,230–64,001,811, 6 genes (within-gene range 0–2): RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1.
- chr11:72,576,141–72,674,591, 5 genes: PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr12:124,337,181–124,337,242, 1 gene (within-gene range 0–2): MIR6880.
- chr14:102,582,888–102,583,177, 1 gene: RN7SL546P.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:2,155,698–2,238,711, 9 genes: TRAF7, CASKIN1, MLST8, BRICD5, PGP, AC009065.7, E4F1, AC009065.1, DNASE1L2.
- chr16:83,899,115–84,002,776, 4 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1, NECAB2.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:142,789–445,939, 10 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.
- chr22:24,011,192–24,189,106, 3 genes: CABIN1, AC253536.3, SUSD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:2,339,150–2,426,699, 1 gene, copy number 5 (within-gene range 2–5): ABCA17P.
- chr20:62,841,005–62,873,076, 3 genes, copy number 5 (within-gene range 2–5): TCFL5, DPH3P1, ARF4P2.
- chr21:10,482,738–13,120,807, 11 genes, copy number 7 (within-gene range 2–7): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 7: SIK1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 8: PWP2.
- chr21:44,158,740–44,160,076, 1 gene, copy number 5: LINC01678.

Autosomal genes at a single copy (total copy number 1): 6,738. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
